Gene-level copy-number profile of tumor specimen TCGA-05-4420-01A from TCGA case TCGA-05-4420, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 41.5 years (15,159 days).
Specimen TCGA-05-4420-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.9c6174fc-37d2-4781-9ce7-10f1d45e82f2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4420-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f4f8e9b9-6cd2-4277-8d24-659ce5d95d72

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 179; copy number 2: 16,132; copy number 3: 15,732; copy number 4: 16,299; copy number 5: 7,668; copy number 6: 3,048; copy number 7: 562; copy number 8: 108; copy number 9: 85.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4420-01A-01D-1204-01): tumor purity 0.59, ploidy 3.49, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 85 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:62,489,495–63,529,761, 6 genes, copy number 9: AC074087.1, HMGN1P11, EXOC5P1, AC097491.1, LARP1BP1, AC093730.1.
- chr6:40,271,566–41,217,947, 20 genes, copy number 9: AL139275.2, TDRG1, LINC00951, AL139275.1, LRFN2, RNU6-250P, AL359475.1, AL033380.1, AL583854.1, UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P.
- chr22:29,387,909–30,627,271, 59 genes, copy number 9 (within-gene range 5–9): AC002059.3, AC000041.1, RFPL4AP6, RFPL1S, RFPL1, NEFH, AC000035.1, THOC5, AC005529.1, NIPSNAP1, NF2, RPEP4, AC004882.1, AC004882.2, CABP7, ZMAT5, Y_RNA, AC004882.3, UQCR10, ASCC2, MTMR3, RNU6-331P, AC003681.1, MIR6818, HORMAD2-AS1, CNN2P1, HORMAD2, AC003071.1, RPS3AP51, AC002378.1, LIF-AS1, LIF, AC004264.1, OSM, AC004264.2, CASTOR1, AC004997.1, TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2, SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1, PES1, AC005006.1, TCN2.

Autosomal genes at a single copy (total copy number 1): 156. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
